Somatic mutation profile of tumor specimen TCGA-TQ-A7RW-01A (aliquot TCGA-TQ-A7RW-01A-11D-A33T-08) from TCGA case TCGA-TQ-A7RW, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 32.3 years (11,804 days).
Specimen TCGA-TQ-A7RW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21ad50c4-9f23-4b16-8d30-490070e88bd0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TQ-A7RW-10A (Blood Derived Normal), aliquot TCGA-TQ-A7RW-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d456dee-d9a2-40c9-94eb-80a85fe1b746

The open-access MAF lists 45 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 69/192 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 34/52 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFDN | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652914; called by muse, mutect2, varscan2
- BCL11A | c.1738T>C p.S580P (on ENST00000335712 / NM_001365609.1; = p.S614P on NM_018014.4) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs1221786015, COSV100185472; called by muse, mutect2, varscan2
- BNC2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs1281294007, COSV101032997; called by muse, mutect2, varscan2
- CCDC6 | c.1014T>G p.N338K | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99569419; called by muse, mutect2, varscan2
- CTDP1 | c.667A>G p.T223A | Missense Mutation (SNP) | VAF 15/195 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99310473; called by muse, mutect2
- CUL5 | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV101263664; called by muse, mutect2
- DACT1 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.057); catalogued as rs920577713, COSV100241812; called by muse, mutect2, varscan2
- DCN | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99272091; called by muse, mutect2, varscan2
- DSCAM | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1263615998, COSV68627736; called by muse, mutect2
- EOLA1 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 102/147 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.047); catalogued as rs781834301, COSV100828406; called by muse, mutect2, varscan2
- GNPNAT1 | c.314T>C p.I105T | Missense Mutation (SNP) | VAF 21/305 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs1277035531, COSV99369502; called by muse, mutect2
- H2BC10 | c.107A>C p.E36A | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100010107; called by muse, mutect2
- HKDC1 | c.1319T>A p.V440D | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100664527; called by muse, mutect2
- INTS4 | c.1021G>C p.E341Q | Missense Mutation (SNP) | VAF 12/381 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV101417174; called by muse, mutect2
- KCNMA1 | c.3416G>A p.R1139Q (on ENST00000286628 / NM_001161352.2; = p.R1081Q on NM_002247.4) | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1397556923, COSV54242497; ClinVar: uncertain significance; called by muse, mutect2
- METTL3 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.189); catalogued as COSV99398242; called by muse, mutect2, varscan2
- NGEF | c.511C>T p.L171F | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV99888978; called by muse, mutect2, varscan2
- NNT | c.2560A>T p.N854Y | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99238833; called by muse, mutect2, varscan2
- OOSP2 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 104/330 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99613370; called by muse, mutect2, varscan2
- PALD1 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.546); catalogued as COSV99698246; called by muse, mutect2
- PPARG | c.1424C>T p.T475M (on ENST00000287820 / NM_015869.5; = p.T445M on NM_005037.7) | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1479145908, COSV55141227; called by muse, mutect2, varscan2
- PPP1R3A | c.3319T>C p.W1107R | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99492717; called by muse, mutect2
- RBM12B | c.88G>C p.D30H | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101197140; called by muse, mutect2
- RDH5 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99141762; called by muse, mutect2
- STXBP4 | c.1502G>A p.G501E | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100894684; called by muse, mutect2
- SUB1 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.114); catalogued as COSV99421602; called by muse, mutect2
- TUBD1 | c.1320C>A p.F440L | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV100360058, COSV57872371, COSV57874284; called by muse, mutect2
- ANGPT1 | c.107T>A p.I36N | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- C17orf78 | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EVC | c.1926G>A p.L642= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99381634; called by muse, mutect2, varscan2
- EYA1 | c.1584T>C p.S528= | Silent (SNP) | VAF 17/293 reads (6%) | catalogued as COSV100379227; called by muse, mutect2
- FOXI1 | c.294C>T p.S98= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs866622107, COSV100089284; called by mutect2, varscan2
- GTF2H3 | c.352C>T p.L118= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as COSV99967556; called by muse, mutect2, varscan2
- KCNJ8 | c.777T>A p.I259= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV99557529; called by muse, mutect2, varscan2
- MCF2L | c.2748C>T p.Y916= (on ENST00000375608; = p.Y884= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as rs1342116430, COSV99995689; called by muse, mutect2, varscan2
- ME1 | c.678C>T p.D226= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as rs186078215; called by muse, mutect2
- NEK9 | c.2691G>A p.V897= | Silent (SNP) | VAF 74/251 reads (29%) | catalogued as COSV99463992; called by muse, mutect2, varscan2
- PCDHA9 | c.2100G>C p.L700= | Silent (SNP) | VAF 70/266 reads (26%) | catalogued as COSV100969430, COSV100969708; called by muse, mutect2, varscan2
- RAB3IP | c.975G>A p.K325= (on ENST00000550536 / NM_175623.4; = p.K309= on NM_022456.5) | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as rs1309713876, COSV99923163; called by muse, mutect2, varscan2
- RANBP2 | c.1641C>T p.N547= | Silent (SNP) | VAF 171/498 reads (34%) | catalogued as rs1255583041, COSV51702347; called by muse, mutect2, varscan2
- TULP4 | c.672G>T p.V224= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as COSV100893431; called by muse, mutect2, varscan2
- ZNF846 | c.54C>T p.T18= | Silent (SNP) | VAF 65/290 reads (22%) | catalogued as COSV101194318; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1616C>T | Intron (SNP) | VAF 11/91 reads (12%) | catalogued as COSV100801447; called by muse, mutect2, varscan2
